Somatic mutation profile of tumor specimen TARGET-20-PATHZC-09A (aliquot TARGET-20-PATHZC-09A-01D) from TARGET case TARGET-20-PATHZC, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 13.0 years (4,753 days).
Specimen TARGET-20-PATHZC-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 897fd911-ba4d-4851-8917-770c174b8c1c.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PATHZC-14A (Bone Marrow Normal), aliquot TARGET-20-PATHZC-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d677f901-ebec-4a78-863f-7db89b53cbb3

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TJP3 | c.1552C>T p.R518* | Nonsense Mutation (SNP) | VAF 21/53 reads (40%) | catalogued as rs754280801; called by muse, mutect2, varscan2
